CCDI case PBBTRA — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neoplasms, NOS; Primary site: Connective, subcutaneous and other soft tissues.
https://portal.gdc.cancer.gov/cases/3f5188a8-e384-4fbf-a94f-a7da72ce67ba

Demographics
Sex at birth: female; Race: white.

Diagnoses (1)
1. Neoplasm, uncertain whether benign or malignant: ICD-O-3 morphology code: 8000/1; Tissue or organ of origin: Connective, subcutaneous and other soft tissues of upper limb and shoulder; Age at diagnosis: 5.2 years (1,914 days).

Biospecimens (3 samples)
- Sample 0DGJ4U: Tissue type: Tumor; Specimen type: Solid Tissue.
- Sample 0DGJ61: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
- Sample 0DGJ7N: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
